Somatic mutation profile of tumor specimen TCGA-2G-AAGY-05A (aliquot TCGA-2G-AAGY-05A-11D-A42Y-10) from TCGA case TCGA-2G-AAGY, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratoma, benign; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 28.3 years (10,338 days).
Specimen TCGA-2G-AAGY-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ead63e62-0fc8-4716-ae57-8c5c7886ddb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGY-10A (Blood Derived Normal), aliquot TCGA-2G-AAGY-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7076225-8e21-4523-9381-0334633ea994

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMA5 | c.9946T>C p.S3316P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1030343328; called by muse, varscan2
- AKAP13 | c.861+1G>T p.X287_splice | Splice Site (SNP) | VAF 28/156 reads (18%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.1799C>A p.A600D (on ENST00000379409; = p.A548D on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SLC38A1 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWA2 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF174 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY2 | c.1882C>T p.L628= | Silent (SNP) | VAF 86/170 reads (51%) | called by muse, mutect2, varscan2
- NADK2 | c.807T>A p.L269= (on ENST00000381937 / NM_001085411.3; = p.L106= on NM_153013.4) | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
